Somatic mutation profile of tumor specimen C3L-00356-01 (aliquot CPT0002130009) from CPTAC case C3L-00356, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 73.0 years (26,668 days).
Specimen C3L-00356-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb29bc16-4cc8-4489-921d-0863cbfa3167.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00356-31 (Blood Derived Normal), aliquot CPT0004350002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24003379-a115-4ff7-bf3c-85871e9fbf65

The open-access MAF lists 48 somatic variants for this specimen: 25 protein-altering or splice-affecting, 18 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 18, Intron 3, 3'UTR 2, Splice Site 1, Splice Region 1, Frame Shift Del 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 106/126 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1064794311, CM973401, COSV52661102, COSV52687307, COSV99402633; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CLDN17 | c.323C>T p.T108I | Missense Mutation (SNP) | VAF 76/223 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.348); catalogued as COSV54523477; called by muse, mutect2, varscan2
- CUL7 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 92/419 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761377936, COSV99539460; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DHTKD1 | c.2439C>A p.F813L | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs1157887940; called by muse, mutect2, varscan2
- MYH2 | c.3359G>A p.R1120H | Missense Mutation (SNP) | VAF 240/279 reads (86%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs752746936, COSV55433509; called by muse, mutect2, varscan2
- ZNF536 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 89/418 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1040675243, COSV62827629, COSV62833791; called by muse, mutect2, varscan2
- ANO6 | c.2102T>G p.V701G | Missense Mutation (SNP) | VAF 72/317 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- ARNT | c.1032+1G>A p.X344_splice | Splice Site (SNP) | VAF 37/109 reads (34%) | called by muse, mutect2, varscan2
- COL11A1 | c.4276G>A p.G1426S | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPNE7 | c.917G>A p.W306* | Nonsense Mutation (SNP) | VAF 78/91 reads (86%) | called by muse, mutect2, varscan2
- CPXM2 | c.2161del p.T721Pfs*25 | Frame Shift Del (DEL) | VAF 177/442 reads (40%) | called by mutect2, pindel, varscan2
- FRY | c.6445C>A p.L2149M | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); called by muse, mutect2
- GIT2 | c.1530T>G p.S510R (on ENST00000355312 / NM_057169.5; = p.S462R on NM_014776.5) | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRM5 | c.2894C>A p.A965D (on ENST00000305447 / NM_001143831.2; = p.A933D on NM_000842.4) | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); called by muse, mutect2
- LRRC9 | c.3441C>G p.N1147K | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2
- MMUT | c.2219A>C p.E740A | Missense Mutation (SNP) | VAF 44/275 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MUC7 | c.631A>T p.T211S | Missense Mutation (SNP) | VAF 108/430 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.245); called by muse, varscan2
- PDZD4 | c.581A>G p.E194G | Missense Mutation (SNP) | VAF 9/165 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PERP | c.75C>A p.F25L | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PPP2R5C | c.1306C>G p.L436V | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- RBM47 | c.917T>C p.L306P | Missense Mutation (SNP) | VAF 111/204 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- RRAS2 | c.214_216del p.Q72del | In Frame Del (DEL) | VAF 73/195 reads (37%) | called by mutect2, pindel, varscan2
- TECRL | c.729A>G p.P243= | Splice Region (SNP) | VAF 22/68 reads (32%) | called by muse, mutect2, varscan2
- TRIM39 | c.563G>C p.S188T | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- ZNF367 | c.823C>A p.L275M | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- A4GNT | c.933C>A p.L311= | Silent (SNP) | VAF 86/1789 reads (5%) | catalogued as COSV99367780; called by muse, mutect2
- ABLIM2 | c.747A>G p.E249= | Silent (SNP) | VAF 35/124 reads (28%) | catalogued as rs1202864734; called by muse, mutect2, varscan2
- CACNG1 | c.264C>T p.P88= | Silent (SNP) | VAF 79/95 reads (83%) | catalogued as rs751712868; called by muse, mutect2, varscan2
- CNTN4 | c.1179C>A p.I393= | Silent (SNP) | VAF 20/250 reads (8%) | catalogued as COSV61871689; called by muse, mutect2
- ERCC4 | c.276C>T p.I92= | Silent (SNP) | VAF 82/272 reads (30%) | called by muse, varscan2
- GOLGA4 | c.3112C>A p.R1038= | Silent (SNP) | VAF 34/62 reads (55%) | catalogued as COSV62710015; called by muse, mutect2, varscan2
- KCP | c.3684C>T p.H1228= (on ENST00000620378; = p.H1352= on NM_001366122.1) | Silent (SNP) | VAF 139/282 reads (49%) | called by muse, mutect2, varscan2
- LATS2 | c.3081G>A p.S1027= | Silent (SNP) | VAF 115/255 reads (45%) | catalogued as rs571711915, COSV66880446; called by muse, mutect2, varscan2
- LMTK3 | c.573C>A p.P191= | Silent (SNP) | VAF 29/110 reads (26%) | called by muse, mutect2, varscan2
- MSANTD3 | c.117G>A p.A39= | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as rs755959697, COSV58493860; called by muse, mutect2, varscan2
- MYCBPAP | c.936C>T p.D312= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as rs145596456; called by muse, mutect2, varscan2
- NKX1-2 | c.231C>A p.G77= | Silent (SNP) | VAF 5/84 reads (6%) | called by muse, mutect2
- ODF3L2 | c.363G>C p.T121= | Silent (SNP) | VAF 43/136 reads (32%) | called by muse, mutect2, varscan2
- PKHD1 | c.9630T>G p.S3210= | Silent (SNP) | VAF 90/628 reads (14%) | called by muse, mutect2, varscan2
- RSPO2 | c.708A>C p.L236= | Silent (SNP) | VAF 69/425 reads (16%) | called by muse, mutect2, varscan2
- SERPINA6 | c.852G>A p.T284= | Silent (SNP) | VAF 14/200 reads (7%) | catalogued as rs774071131, COSV58585426; called by muse, mutect2
- SIK3 | c.1107T>C p.Y369= (on ENST00000445177 / NM_001366686.2; = p.Y375= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/231 reads (16%) | catalogued as rs779641078; called by muse, mutect2, varscan2
- SLC16A1 | c.1440A>T p.A480= | Silent (SNP) | VAF 138/249 reads (55%) | called by muse, mutect2, varscan2
- ANKRD66 | c.557+2174C>T | Intron (SNP) | VAF 27/64 reads (42%) | called by muse, mutect2, varscan2
- FOXP2 | c.*1393A>G | 3'UTR (SNP) | VAF 24/111 reads (22%) | called by muse, mutect2, varscan2
- FOXP2 | c.*2991G>A | 3'UTR (SNP) | VAF 79/152 reads (52%) | catalogued as rs1260229112, COSV63483615; called by muse, mutect2, varscan2
- MYO15B | c.2361-14C>T | Intron (SNP) | VAF 178/238 reads (75%) | called by muse, mutect2, varscan2
- SLC30A2 | c.271+641C>T | Intron (SNP) | VAF 9/172 reads (5%) | called by muse, mutect2
